Somatic mutation profile of tumor specimen ALCH-AFAX-TTP1-A (aliquot ALCH-AFAX-TTP1-A-2-0-D-A636-36) from ALCHEMIST case ALCH-AFAX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.0 years (21,201 days).
Specimen ALCH-AFAX-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba9785de-9428-4d74-8f06-d703be187b3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFAX-NB1-A (Blood Derived Normal), aliquot ALCH-AFAX-NB1-A-1-0-D-A635-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79dc3125-e3f2-4074-9f89-a6c156b0ee4b

The open-access MAF lists 46 somatic variants for this specimen: 30 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 13, Intron 2, In Frame Del 2, 3'UTR 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 122/982 reads (12%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- RAG1 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 45/822 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs758288006, CM1313163, COSV100201112, COSV55024544; ClinVar: pathogenic; called by muse, mutect2
- ACAN | c.5849C>G p.T1950R | Missense Mutation (SNP) | VAF 24/382 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs763076469, COSV61358396; called by muse, mutect2
- ACTL7B | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 19/407 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV65927444; called by muse, mutect2
- CPSF6 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 248/554 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.224); catalogued as COSV57017388; called by muse, mutect2, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 8/63 reads (13%) | catalogued as rs754135731; called by mutect2, varscan2*
- FHAD1 | c.2593G>A p.E865K | Missense Mutation (SNP) | VAF 34/546 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV58986915; called by muse, mutect2
- GNE | c.2000C>T p.A667V (on ENST00000396594 / NM_001128227.3; = p.A636V on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/738 reads (6%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs756488394, COSV64953467; ClinVar: uncertain significance; called by muse, mutect2
- MRGPRX1 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 42/696 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs531949208, COSV57106494; called by muse, mutect2
- MYL2 | c.93+3G>C | Splice Region (SNP) | VAF 47/460 reads (10%) | catalogued as rs113465073; called by muse, varscan2
- PAPPA2 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 33/592 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs746410678, COSV62775917; called by muse, mutect2
- PDS5A | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 46/499 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.281); catalogued as COSV57826113; called by muse, mutect2
- SATB2 | c.1426G>A p.V476M | Missense Mutation (SNP) | VAF 66/750 reads (9%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.968); catalogued as rs759458466; called by muse, mutect2
- SHQ1 | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 22/392 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs145150877; called by muse, mutect2
- APOOL | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- BOD1L1 | c.3734C>G p.A1245G | Missense Mutation (SNP) | VAF 10/217 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2
- CCDC40 | c.2240A>T p.E747V | Missense Mutation (SNP) | VAF 36/593 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.313); called by muse, mutect2
- CD19 | c.686A>G p.E229G | Missense Mutation (SNP) | VAF 18/668 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2
- CNRIP1 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 22/517 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.117); called by muse, mutect2
- EFCAB5 | c.754A>T p.T252S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- HIVEP1 | c.2626G>T p.D876Y | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IL21R | c.1133C>A p.T378K | Missense Mutation (SNP) | VAF 45/333 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LUZP1 | c.1321A>G p.T441A | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- MMP3 | c.35T>C p.V12A | Missense Mutation (SNP) | VAF 14/446 reads (3%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2
- NEURL1B | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2
- PAK3 | c.962del p.K321Rfs*4 (on ENST00000262836 / NM_001324328.2; = p.K306Rfs*4 on NM_002578.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 56/266 reads (21%) | called by mutect2, pindel, varscan2
- PPP1R12A | c.2497G>A p.D833N | Missense Mutation (SNP) | VAF 39/512 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2
- RALGAPB | c.4351T>G p.S1451A | Missense Mutation (SNP) | VAF 47/633 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2
- SP7 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 388/1306 reads (30%) | SIFT tolerated (0.88); PolyPhen benign (0.025); called by muse, varscan2
- TRIM42 | c.962A>G p.H321R | Missense Mutation (SNP) | VAF 38/445 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CLASP2 | c.3552G>A p.L1184= (on ENST00000359576; = p.L1183= on NM_015097.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- DNAH11 | c.6777T>C p.D2259= | Silent (SNP) | VAF 28/538 reads (5%) | called by muse, mutect2
- FBXO21 | c.1242C>G p.L414= | Silent (SNP) | VAF 9/251 reads (4%) | called by muse, mutect2
- GBP6 | c.1695G>A p.K565= | Silent (SNP) | VAF 15/187 reads (8%) | called by muse, mutect2
- KIFC1 | c.1281C>T p.D427= | Silent (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- OR52A5 | c.939A>G p.K313= | Silent (SNP) | VAF 10/72 reads (14%) | called by muse, varscan2
- PCDHGA12 | c.2121C>T p.F707= | Silent (SNP) | VAF 34/540 reads (6%) | catalogued as rs865848752, COSV52750761; called by muse, mutect2
- PIEZO2 | c.4059C>T p.N1353= | Silent (SNP) | VAF 18/212 reads (8%) | catalogued as rs771246552; called by muse, mutect2
- PRAF2 | c.93G>A p.Q31= | Silent (SNP) | VAF 11/235 reads (5%) | catalogued as rs35035067; called by muse, mutect2
- QRICH1 | c.1659G>T p.L553= | Silent (SNP) | VAF 23/202 reads (11%) | called by muse, mutect2
- RBP4 | c.99C>T p.F33= | Silent (SNP) | VAF 24/471 reads (5%) | catalogued as COSV65159601; called by muse, mutect2
- RNF113A | c.318G>A p.A106= | Silent (SNP) | VAF 22/289 reads (8%) | catalogued as rs1329989457, COSV65097493; called by muse, mutect2
- UTF1 | c.909G>A p.L303= | Silent (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- CARD19 | c.*853C>G | 3'UTR (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2, varscan2
- HAND2-AS1 | n.512+1266G>C | Intron (SNP) | VAF 6/133 reads (5%) | called by muse, mutect2
- PDE4DIP | c.637-7687C>G | Intron (SNP) | VAF 11/272 reads (4%) | catalogued as COSV100521994, COSV57689637; called by muse, mutect2
